Somatic mutation profile of cancer-model specimen HCM-BROD-0047-C71-85B (Adherent Cell Line, passage 10; aliquot HCM-BROD-0047-C71-85B-01D-A77E-36), derived from the recurrence tumor of HCMI case HCM-BROD-0047-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,404 days).
Specimen HCM-BROD-0047-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b2e8e29-0f40-47b5-b3f6-5a213e71066a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0047-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0047-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29eddd1e-f383-415c-b517-0bcd0cb82e72

The open-access MAF lists 198 somatic variants for this specimen: 127 protein-altering or splice-affecting, 49 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 49, Frame Shift Del 9, Intron 8, Nonsense Mutation 7, Splice Site 6, 3'UTR 5, RNA 4, 5'Flank 4, In Frame Del 2, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 80/122 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 316/316 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.12469A>C p.M4157L | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs774085026, COSV71289926; called by muse, mutect2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 181/186 reads (97%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, mutect2, varscan2
- BPIFB6 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 134/366 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.181); catalogued as rs778553438; called by muse, mutect2
- BTBD7 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs374714816; called by muse, mutect2, varscan2
- CACNA1D | c.1417T>C p.S473P | Missense Mutation (SNP) | VAF 20/761 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV55461738; called by muse, mutect2
- CLCA4 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as rs768554342, COSV55366417; called by muse, mutect2
- DNAH3 | c.9871C>T p.R3291W | Missense Mutation (SNP) | VAF 166/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772203216, COSV54535961; called by muse, mutect2, varscan2
- GEMIN4 | c.1381G>C p.V461L | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56748269; called by muse, mutect2
- HDC | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 124/552 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367618872, COSV51070116; called by muse, mutect2, varscan2
- HSPA12A | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 158/161 reads (98%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as rs781974587, COSV65022946; called by muse, varscan2
- KEL | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 741/1519 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147851584, CM165859, COSV62335323; called by muse, mutect2, varscan2
- LIPC | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 261/482 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.438); catalogued as rs756311428; called by muse, mutect2, varscan2
- LTBP1 | c.3169G>T p.E1057* (on ENST00000404816 / NM_206943.4; = p.E731* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 79/240 reads (33%) | catalogued as COSV55383251; called by muse, mutect2, varscan2
- MRGPRX4 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1444628507, COSV58589735; called by muse, mutect2, varscan2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 128/352 reads (36%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- MUC6 | c.2210C>T p.T737I | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as rs563244857; called by muse, mutect2
- NALCN | c.3712A>G p.T1238A | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as rs1383609221; called by muse, mutect2, varscan2
- OBSCN | c.10432C>A p.P3478T | Missense Mutation (SNP) | VAF 114/521 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV52753344, COSV52757886; called by muse, mutect2, varscan2
- OR2T4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 220/431 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs141022739; called by muse, mutect2, varscan2
- OTUD7A | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 13/423 reads (3%) | catalogued as rs757148409, COSV61036342; called by muse, mutect2
- PCLO | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 67/469 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs746437072, COSV61626152; called by muse, mutect2, varscan2
- PEX6 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 228/463 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs575358435; called by muse, mutect2, varscan2
- PLCB2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 115/197 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs938166611; called by muse, mutect2, varscan2
- PPP1R16B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 138/299 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs376987738; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 92/118 reads (78%) | catalogued as rs146650273; called by pindel, varscan2
- SHANK1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 125/260 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53253397, COSV53258492; called by muse, mutect2, varscan2
- SLC26A1 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs565674546; called by muse, mutect2, varscan2
- SPATA22 | c.900+1G>A p.X300_splice | Splice Site (SNP) | VAF 39/63 reads (62%) | catalogued as rs1156746289; called by muse, mutect2, varscan2
- SPRR1B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs781282352, COSV100198426; called by muse, mutect2, varscan2
- STK31 | c.1950G>T p.K650N | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63455850; called by muse, mutect2
- TAF1L | c.1577A>G p.E526G | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54265915; called by muse, mutect2, varscan2
- TNFSF9 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 192/428 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs753168707; called by muse, varscan2
- TRAV21 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 164/369 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs762806352; called by muse, mutect2, varscan2
- TRPM5 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 247/247 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs376847854; called by muse, mutect2, varscan2
- TSPAN6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV65957487; called by muse, mutect2, varscan2
- TTC34 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 114/115 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs769408367; called by muse, mutect2, varscan2
- TTYH1 | c.126+2T>C p.X42_splice | Splice Site (SNP) | VAF 35/68 reads (51%) | catalogued as rs1340739545; called by muse, mutect2, varscan2
- WAC | c.1621A>G p.T541A | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs991762624; called by muse, mutect2, varscan2
- ZMYM6 | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV64120079; called by muse, mutect2
- ZNF423 | c.3721G>A p.V1241M (on ENST00000563137 / NM_001379286.1; = p.V1233M on NM_015069.4) | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV52206589; called by muse, mutect2, varscan2
- ZSCAN5C | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 120/371 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.428); catalogued as rs762862197; called by muse, mutect2, varscan2
- ACE | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ADAMTS20 | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ANO3 | c.1634C>A p.T545N | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- APOA1 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- C12orf50 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAB39 | c.288del p.D97Tfs*35 | Frame Shift Del (DEL) | VAF 36/50 reads (72%) | called by mutect2, pindel, varscan2
- CACNG3 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CAP1 | c.635del p.P212Lfs*6 | Frame Shift Del (DEL) | VAF 100/315 reads (32%) | called by mutect2, pindel, varscan2
- CBL | c.2305_2309del p.N769Gfs*2 | Frame Shift Del (DEL) | VAF 136/363 reads (37%) | called by mutect2, pindel, varscan2
- CCER2 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 83/785 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCL17 | c.211del p.A71Pfs*11 | Frame Shift Del (DEL) | VAF 73/388 reads (19%) | called by mutect2, pindel, varscan2
- COL22A1 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CPNE7 | c.1388G>T p.C463F | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CR1 | c.1749del p.H585Tfs*57 (on ENST00000367051; = p.H1035Tfs*57 on NM_000651.6) | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, varscan2
- CRACDL | c.28A>T p.K10* | Nonsense Mutation (SNP) | VAF 62/305 reads (20%) | called by muse, mutect2, varscan2
- CTXN3 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUX1 | c.1177C>T p.Q393* (on ENST00000292535 / NM_181552.4; = p.Q404* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 138/488 reads (28%) | called by muse, mutect2, varscan2
- CWH43 | c.1267-1_1268del p.X423_splice | Splice Site (DEL) | VAF 46/78 reads (59%) | called by mutect2, pindel, varscan2
- DCAF12L1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF15 | c.230+2T>C p.X77_splice | Splice Site (SNP) | VAF 131/399 reads (33%) | called by muse, mutect2, varscan2
- DDRGK1 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- DLK1 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EIF2AK4 | c.2468T>C p.V823A | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ENPP4 | c.9A>T p.L3F | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.2284T>G p.L762V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FKBP5 | c.541T>C p.F181L | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FPR1 | c.526_528del p.C176del | In Frame Del (DEL) | VAF 182/190 reads (96%) | called by mutect2, pindel, varscan2
- FST | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- GATA2 | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- GOLGA8J | c.72del p.N24Kfs*49 | Frame Shift Del (DEL) | VAF 101/353 reads (29%) | called by mutect2, pindel, varscan2
- HAPLN3 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2
- HERC5 | c.1910A>G p.N637S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- HIF3A | c.682C>G p.H228D (on ENST00000377670 / NM_152795.4; = p.H159D on NM_022462.4) | Missense Mutation (SNP) | VAF 185/313 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- INIP | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- INTS4 | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KLK2 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 125/218 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- LAMA1 | c.7965-4del | Splice Region (DEL) | VAF 64/177 reads (36%) | called by mutect2, pindel, varscan2
- LIMK2 | c.1381T>G p.L461V | Missense Mutation (SNP) | VAF 9/273 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2
- MAP2 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MRGPRF | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MUC16 | c.6512C>A p.T2171K | Missense Mutation (SNP) | VAF 117/437 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.1060A>T p.R354W | Missense Mutation (SNP) | VAF 201/204 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MUC22 | c.4326_4331del p.S1443_E1444del | In Frame Del (DEL) | VAF 188/826 reads (23%) | called by mutect2, varscan2
- MYH11 | c.3507-2A>T p.X1169_splice | Splice Site (SNP) | VAF 31/675 reads (5%) | called by muse, mutect2
- MYO1B | c.1673A>T p.N558I | Missense Mutation (SNP) | VAF 273/276 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- NLRP2 | c.2975del p.N992Ifs*8 | Frame Shift Del (DEL) | VAF 192/488 reads (39%) | called by mutect2, pindel, varscan2
- OR2A2 | c.594A>G p.I198M | Missense Mutation (SNP) | VAF 451/892 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- OR2L3 | c.645T>A p.C215* | Nonsense Mutation (SNP) | VAF 182/317 reads (57%) | called by muse, mutect2, varscan2
- OR4K5 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- OS9 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PADI1 | c.990_995dup p.K331_A332dup | In Frame Ins (INS) | VAF 47/53 reads (89%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.812A>T p.E271V (on ENST00000374531 / NM_001037293.2; = p.E303V on NM_053016.6) | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPPA | c.4531A>G p.S1511G | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PCDHA2 | c.1618G>C p.A540P | Missense Mutation (SNP) | VAF 885/897 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PFKL | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKHD1 | c.11335C>A p.P3779T | Missense Mutation (SNP) | VAF 105/195 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNISR | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 145/269 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PPL | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRODH2 | c.695T>C p.L232P (on ENST00000301175; = p.L156P on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTH1R | c.1212-2A>T p.X404_splice | Splice Site (SNP) | VAF 24/870 reads (3%) | called by muse, mutect2
- RECK | c.1628T>C p.I543T | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- RFXANK | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 363/1190 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS10 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPL15 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 37/233 reads (16%) | called by muse, mutect2, varscan2
- RREB1 | c.3340A>C p.T1114P | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RSF1 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- RYR1 | c.2246T>A p.L749H | Missense Mutation (SNP) | VAF 96/674 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYL1 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- SIPA1L3 | c.4021A>G p.M1341V | Missense Mutation (SNP) | VAF 65/495 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A51 | c.432G>C p.L144F | Missense Mutation (SNP) | VAF 204/363 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC4A2 | c.3608T>C p.V1203A | Missense Mutation (SNP) | VAF 181/535 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLU7 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SRBD1 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF2 | c.2930C>T p.T977I | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TDRD7 | c.2309A>T p.K770M | Missense Mutation (SNP) | VAF 123/620 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TEX13C | c.2789A>T p.Q930L | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TNNI2 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL5 | c.3449T>G p.F1150C | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, varscan2
- UFL1 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2
- UGT2B11 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2
- ZNF285 | c.1301G>C p.G434A | Missense Mutation (SNP) | VAF 146/147 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF461 | c.1586A>T p.K529M | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZNF721 | c.2604_2605del p.Y869Cfs*3 (on ENST00000338977; = p.Y881Cfs*3 on NM_133474.4) | Frame Shift Del (DEL) | VAF 89/291 reads (31%) | called by mutect2, pindel, varscan2
- ZNF732 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, varscan2
- ADAMTS5 | c.342G>T p.V114= | Silent (SNP) | VAF 11/340 reads (3%) | called by muse, mutect2
- AFAP1L1 | c.195G>T p.G65= | Silent (SNP) | VAF 23/339 reads (7%) | called by muse, mutect2
- AHNAK2 | c.5151C>A p.V1717= | Silent (SNP) | VAF 117/1028 reads (11%) | called by muse, mutect2, varscan2
- APOBR | c.2205G>A p.A735= (on ENST00000431282; = p.A744= on NM_018690.4) | Silent (SNP) | VAF 80/163 reads (49%) | catalogued as rs369577053; called by muse, mutect2, varscan2
- BEGAIN | c.1431C>T p.S477= | Silent (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- BPIFB6 | c.276C>A p.S92= | Silent (SNP) | VAF 134/363 reads (37%) | called by muse, mutect2
- BRINP3 | c.1945C>T p.L649= | Silent (SNP) | VAF 33/290 reads (11%) | catalogued as rs1454955105; called by muse, mutect2, varscan2
- CAMTA1 | c.1860C>T p.D620= | Silent (SNP) | VAF 172/172 reads (100%) | catalogued as rs569086347, COSV57895134; called by muse, mutect2, varscan2
- CATSPERG | c.2271C>T p.R757= | Silent (SNP) | VAF 295/1042 reads (28%) | called by muse, mutect2, varscan2
- CUX1 | c.1176G>T p.L392= (on ENST00000292535 / NM_181552.4; = p.L403= on NM_001913.5) | Silent (SNP) | VAF 136/484 reads (28%) | called by muse, mutect2, varscan2
- CYBB | c.150G>C p.L50= | Silent (SNP) | VAF 168/382 reads (44%) | called by muse, mutect2, varscan2
- DIDO1 | c.4143C>T p.D1381= | Silent (SNP) | VAF 265/554 reads (48%) | called by muse, mutect2, varscan2
- DYSF | c.2718C>T p.D906= | Silent (SNP) | VAF 120/358 reads (34%) | catalogued as rs772806555, COSV50266247; called by muse, mutect2, varscan2
- ELAVL2 | c.363T>C p.S121= | Silent (SNP) | VAF 73/271 reads (27%) | called by muse, mutect2, varscan2
- FAM216B | c.300T>C p.A100= | Silent (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- FLG | c.1563G>T p.G521= | Silent (SNP) | VAF 355/650 reads (55%) | catalogued as rs763639841; called by muse, mutect2, varscan2
- FOXD4L4 | c.1017G>A p.Q339= | Silent (SNP) | VAF 194/1164 reads (17%) | called by muse, mutect2, varscan2
- FZD10 | c.1422C>T p.I474= | Silent (SNP) | VAF 166/330 reads (50%) | catalogued as COSV99969621; called by muse, mutect2, varscan2
- GCNT2 | c.321C>T p.F107= | Silent (SNP) | VAF 42/515 reads (8%) | catalogued as rs113929825; called by muse, mutect2
- GIMAP8 | c.1638G>A p.A546= | Silent (SNP) | VAF 111/297 reads (37%) | catalogued as rs897850406, COSV56231089; called by muse, mutect2, varscan2
- GIPC1 | c.219C>A p.I73= | Silent (SNP) | VAF 145/1121 reads (13%) | called by muse, mutect2, varscan2
- GUCY2D | c.1311G>A p.P437= | Silent (SNP) | VAF 251/252 reads (100%) | catalogued as rs775635196, COSV54696534; called by muse, mutect2, varscan2
- HAS1 | c.219C>T p.F73= | Silent (SNP) | VAF 237/238 reads (100%) | called by muse, mutect2, varscan2
- HDAC6 | c.111G>A p.K37= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- HMCN2 | c.5154G>A p.Q1718= | Silent (SNP) | VAF 30/686 reads (4%) | called by muse, mutect2
- HMCN2 | c.12579G>A p.A4193= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as rs942933262, COSV52983544; called by muse, mutect2, varscan2
- IQGAP2 | c.2967A>G p.V989= | Silent (SNP) | VAF 181/750 reads (24%) | called by muse, mutect2, varscan2
- MMP14 | c.1038T>C p.N346= | Silent (SNP) | VAF 65/261 reads (25%) | called by muse, mutect2, varscan2
- MRGPRF | c.921G>A p.R307= | Silent (SNP) | VAF 73/215 reads (34%) | called by muse, mutect2, varscan2
- NEIL3 | c.1599T>C p.C533= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as rs1201712501; called by muse, mutect2, varscan2
- NLRP2 | c.1764C>T p.C588= | Silent (SNP) | VAF 404/412 reads (98%) | catalogued as rs781443340, COSV54759813; called by muse, mutect2, varscan2
- PCNX2 | c.2958G>A p.L986= | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- PPL | c.1194G>A p.P398= | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as rs752842442, COSV100630759; called by muse, mutect2, varscan2
- PRRC2B | c.3693T>C p.S1231= | Silent (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- RYR1 | c.5400T>C p.P1800= | Silent (SNP) | VAF 109/309 reads (35%) | called by muse, mutect2, varscan2
- SCN5A | c.873C>T p.N291= | Silent (SNP) | VAF 96/172 reads (56%) | catalogued as rs376515775; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELE | c.315G>A p.R105= | Silent (SNP) | VAF 119/237 reads (50%) | catalogued as rs759912786, COSV60974350; called by muse, mutect2, varscan2
- SEMG2 | c.285A>G p.K95= | Silent (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- SEZ6 | c.402G>A p.Q134= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- TBR1 | c.1533C>A p.A511= | Silent (SNP) | VAF 75/169 reads (44%) | called by muse, mutect2, varscan2
- THSD7B | c.786C>T p.S262= | Silent (SNP) | VAF 125/253 reads (49%) | catalogued as rs576768669, COSV55675824, COSV55679461; called by muse, mutect2, varscan2
- TREML1 | c.720T>C p.F240= | Silent (SNP) | VAF 69/382 reads (18%) | called by muse, mutect2, varscan2
- VAX2 | c.606G>A p.A202= | Silent (SNP) | VAF 105/285 reads (37%) | catalogued as rs782471705, COSV52265915; called by muse, mutect2, varscan2
- VRK1 | c.336G>A p.K112= | Silent (SNP) | VAF 12/249 reads (5%) | called by muse, mutect2
- WNK2 | c.6639T>A p.P2213= (on ENST00000297954 / NM_001282394.1; = p.P2176= on NM_006648.3) | Silent (SNP) | VAF 17/324 reads (5%) | called by muse, mutect2
- WWC1 | c.1467C>T p.A489= | Silent (SNP) | VAF 226/226 reads (100%) | called by muse, mutect2, varscan2
- ZNF18 | c.303G>A p.V101= | Silent (SNP) | VAF 176/177 reads (99%) | catalogued as rs1217188275, COSV59550512; called by muse, mutect2, varscan2
- ZNF335 | c.462T>C p.S154= | Silent (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- ZNF404 | c.1071T>C p.C357= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV60986809; called by muse, mutect2, varscan2
- AC005008.1 | chr7:81187834 A>G | 5'Flank (SNP) | VAF 57/400 reads (14%) | called by muse, mutect2, varscan2
- AHRR | c.245-8802G>A | Intron (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- ARFRP1 | c.418-490C>G | Intron (SNP) | VAF 28/126 reads (22%) | called by muse, varscan2
- BAIAP2 | chr17:81033193 T>C | 5'Flank (SNP) | VAF 16/126 reads (13%) | called by muse, varscan2
- CCDC7 | chr10:32876457 T>C | 3'Flank (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- DCHS2 | n.4055T>C | RNA (SNP) | VAF 15/43 reads (35%) | called by mutect2, varscan2
- GIT2 | c.1393-1363C>G | Intron (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- GPRC5B | c.*3089T>C | 3'UTR (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- GUCY2EP | n.1194G>A | RNA (SNP) | VAF 37/42 reads (88%) | called by mutect2, varscan2
- HCN1 | c.*4C>T | 3'UTR (SNP) | VAF 201/445 reads (45%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2053G>T | Intron (SNP) | VAF 19/530 reads (4%) | called by muse, mutect2
- LINC02090 | n.133G>A | RNA (SNP) | VAF 12/246 reads (5%) | catalogued as rs1282670039; called by muse, mutect2
- LRRC39 | c.953-272G>A | Intron (SNP) | VAF 48/205 reads (23%) | called by muse, varscan2
- MIR7-3 | n.74A>T | RNA (SNP) | VAF 43/225 reads (19%) | called by muse, mutect2, varscan2
- MRPS18A | c.377-20C>T | Intron (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- ODF2 | c.1911+35C>T | Intron (SNP) | VAF 20/510 reads (4%) | catalogued as rs868479128; called by muse, mutect2
- PTPN18 | c.376-9C>T | Intron (SNP) | VAF 62/302 reads (21%) | called by muse, mutect2, varscan2
- QRICH2 | c.*45C>T | 3'UTR (SNP) | VAF 145/145 reads (100%) | catalogued as rs770433642, COSV53156824; called by muse, mutect2, varscan2
- RNF32 | chr7:156640185 G>A | 5'Flank (SNP) | VAF 111/720 reads (15%) | catalogued as rs1197883958; called by muse, mutect2, varscan2
- RPL31 | c.*2C>A | 3'UTR (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- SCN4B | c.*2757G>A | 3'UTR (SNP) | VAF 223/224 reads (100%) | catalogued as rs1232026663; called by muse, mutect2, varscan2
- SNORD114-14 | chr14:100969830 A>G | 5'Flank (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
